Surgical pathology report (de-identified scan), TCGA case TCGA-DU-7012, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Henry Ford Hospital, specimen TCGA-DU-7012-01A (Primary Tumor).

PATHOLOGICAL DIAGNOSTICS:

LEFT TEMPORAL LOBE BIOPSY: ANAPLASTIC GEMISTOCYTIC ASTROCYTOMA.
(MIB-1: ABOUT 12%)

Operation/Specimen: Left temporal brain tumor

Clinical History and Pre-Op Dx:

GROSS PATHOLOGY:

SPECIMEN: Left temporal brain tumor

FIXATIVE: Saline

GENERAL: Irregular tan white friable multiple soft tissue
fragments, .3 cm to 3 x 1.5 x 1.5 cm. Cut surface
focally hemorrhagic and necrotic.

SECTIONS: 1-5 representative.
[REDACTED]

MICROSCOPIC: Sections show a diffusely infiltrating astrocytoma with extension into the leptomeninges. The tumor is predominantly gemistocytic mixed with undifferentiated cells. The tumor shows hypercellularity, nuclear pleomorphism, and hyperchromasia. Mitotic figures are noted. Vascular endothelial hyperplasia is mild.

Necrosis

is absent. Tumor cells are strongly positive for GFAP.

Immunostain for MIB-1 on section of block 3 shows that the proliferative index of the tumor is about 12%.
[REDACTED]

Source: NCI Genomic Data Commons file 80ad320e-ccb3-45cc-8947-c241886de80a (TCGA-DU-7012.097539A1-A885-478D-9A11-087D6DBF8970.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).